Somatic mutation profile of tumor specimen TCGA-97-7938-01A (aliquot TCGA-97-7938-01A-11D-2167-08) from TCGA case TCGA-97-7938, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.6 years (27,980 days).
Specimen TCGA-97-7938-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) addc7bff-7f2f-41ea-800e-e66ce8734f28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-7938-10A (Blood Derived Normal), aliquot TCGA-97-7938-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c68dd550-fd19-4323-9d07-6387be57ee96

The open-access MAF lists 428 somatic variants for this specimen: 320 protein-altering or splice-affecting, 91 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 276, Silent 91, Nonsense Mutation 26, Frame Shift Del 8, Intron 6, Splice Site 5, RNA 5, 5'Flank 3, 3'UTR 3, Splice Region 2, Frame Shift Ins 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.375+2T>A p.X125_splice | Splice Site (SNP) | VAF 7/79 reads (9%) | hotspot (GDC flag); catalogued as rs1555526469, CS147127, COSV52663814, COSV52664353, COSV52730362; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AARS2 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs745852325, COSV55113050; called by muse, mutect2, varscan2
- ABCA4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.2); catalogued as COSV64670554; called by muse, mutect2, varscan2
- ABCG8 | c.1531T>C p.Y511H | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55390197; called by muse, mutect2, varscan2
- ACTL9 | c.835A>T p.T279S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV61004499; called by muse, mutect2, varscan2
- ADAMTS14 | c.799G>T p.V267L | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV64599341; called by muse, mutect2, varscan2
- ADAMTS16 | c.229C>A p.H77N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as COSV56976127; called by muse, mutect2, varscan2
- ADAMTS18 | c.3347C>A p.P1116Q | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV51398236, COSV51423100; called by muse, mutect2, varscan2
- ADCY2 | c.2214G>T p.P738= | Splice Region (SNP) | VAF 51/254 reads (20%) | catalogued as COSV57856970; called by muse, mutect2, varscan2
- ADCY7 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs142217351; called by muse, mutect2
- ADGRB2 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV99926203; called by muse, mutect2, varscan2
- ADGRL4 | c.1879C>G p.L627V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV66058644; called by muse, mutect2, varscan2
- ADGRV1 | c.5758A>G p.I1920V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV67977378; called by muse, mutect2, varscan2
- AGL | c.50A>T p.K17I | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV54047358, COSV54050810; called by muse, mutect2, varscan2
- AIFM1 | c.571C>A p.L191M | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV54852299; called by muse, mutect2, varscan2
- ALDH7A1 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV63160682; called by muse, mutect2, varscan2
- ALG10 | c.1184G>T p.W395L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV56791520; called by muse, mutect2, varscan2
- ALG13 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV52634675; called by muse, mutect2, varscan2
- ALK | c.3895G>T p.E1299* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as COSV66555583, COSV66588111, COSV66591825; called by muse, mutect2, varscan2
- ALOX12B | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV59870676; called by muse, mutect2, varscan2
- ALPK2 | c.3693G>T p.E1231D | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as COSV64489767; called by muse, mutect2, varscan2
- ANKRD26 | c.4539G>C p.Q1513H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV65773562; called by muse, mutect2, varscan2
- ANO9 | c.309C>A p.H103Q | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs145003945, COSV60447976; called by muse, mutect2, varscan2
- APOH | c.468T>A p.Y156* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as COSV52771124; called by muse, mutect2, varscan2
- ARHGEF39 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV58396274; called by muse, varscan2
- ARID1A | c.3247G>T p.G1083C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61370518; called by muse, mutect2, varscan2
- ASH1L | c.5641G>T p.E1881* | Nonsense Mutation (SNP) | VAF 42/85 reads (49%) | catalogued as COSV64204924; called by muse, mutect2, varscan2
- ATP11B | c.2252G>T p.R751I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV100017760; called by muse, mutect2, varscan2
- ATP11C | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59558882; called by muse, mutect2, varscan2
- B3GALT5 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs140140179; called by muse, mutect2, varscan2
- BCL11B | c.730C>A p.H244N (on ENST00000357195 / NM_001282237.2; = p.H173N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61732840; called by muse, mutect2, varscan2
- BCORL1 | c.206G>T p.S69I | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV54388884; called by muse, varscan2
- BFSP2 | c.342C>G p.C114W | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs371179115, COSV56586024; called by muse, mutect2, varscan2
- BOD1L1 | c.5019A>G p.I1673M | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV50006285; called by muse, mutect2, varscan2
- BPIFB6 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62754063; called by muse, mutect2, varscan2
- BRINP3 | c.208G>T p.G70* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100818740; called by muse, mutect2
- BRWD1 | c.6623A>T p.H2208L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV58999821; called by muse, mutect2, varscan2
- C1orf94 | c.769A>G p.K257E (on ENST00000488417 / NM_001134734.2; = p.K67E on NM_032884.5) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV64912836; called by muse, mutect2, varscan2
- C8A | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV63482982; called by muse, mutect2, varscan2
- CALB2 | c.414C>A p.D138E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.225); catalogued as COSV56937800; called by muse, mutect2, varscan2
- CAPN3 | c.343G>T p.G115* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV58818852; called by muse, mutect2, varscan2
- CARMIL3 | c.3838C>A p.P1280T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53742278; called by muse, mutect2, varscan2
- CBARP | c.388G>T p.E130* (on ENST00000382477; = p.E136* on NM_152769.3) | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV53067409, COSV53071288; called by muse, mutect2
- CCDC89 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as COSV57033460; called by muse, mutect2, varscan2
- CCSER1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100391449; called by muse, mutect2
- CD1E | c.814A>T p.T272S | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.268); catalogued as COSV63769820, COSV63770568; called by muse, mutect2, varscan2
- CFAP43 | c.3350T>A p.L1117H | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV63851683; called by muse, mutect2, varscan2
- CHMP1B | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as COSV52322518; called by muse, mutect2, varscan2
- CHRNB4 | c.765C>A p.Y255* | Nonsense Mutation (SNP) | VAF 26/122 reads (21%) | catalogued as COSV55714447; called by muse, mutect2, varscan2
- CKAP2 | c.1459G>A p.A487T (on ENST00000378037 / NM_001098525.2; = p.A486T on NM_018204.5) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51620623; called by muse, mutect2
- CMKLR1 | c.488T>A p.I163N (on ENST00000312143 / NM_001142344.2; = p.I161N on NM_004072.3) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV56435924; called by muse, mutect2, varscan2
- CNKSR2 | c.2154C>A p.C718* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV54248664, COSV54251671; called by muse, mutect2, varscan2
- CNTN3 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as COSV55161810, COSV99723580; called by muse, mutect2, varscan2
- COA7 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs757443792, COSV101034297, COSV65299067; called by muse, mutect2, varscan2
- COIL | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV53593553; called by muse, mutect2, varscan2
- COL11A1 | c.4366G>T p.G1456C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100616472; called by muse, mutect2, varscan2
- COL20A1 | c.2728G>T p.E910* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as rs374617184, COSV58927036; called by muse, mutect2, varscan2
- COL4A5 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100087669; called by muse, mutect2, varscan2
- COX5B | c.220A>G p.R74G | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV51480619; called by muse, mutect2, varscan2
- CPS1 | c.2590C>A p.L864I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV51800595; called by muse, mutect2, varscan2
- CRIM1 | c.358C>T p.L120F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV54858733; called by muse, mutect2, varscan2
- CSMD3 | c.590G>C p.G197A | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs962355266, COSV52090752, COSV52136577, COSV52142448; called by muse, mutect2, varscan2
- CTNNA2 | c.2220T>A p.D740E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58131598, COSV58151398; called by muse, mutect2, varscan2
- CUX2 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs774991259, COSV55622878; called by muse, mutect2, varscan2
- CXorf21 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100973343, COSV66762344, COSV66762529; called by muse, mutect2, varscan2
- CYP17A1 | c.601T>C p.Y201H | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM051447, COSV64004679; called by muse, mutect2, varscan2
- DDX46 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62798287; called by muse, mutect2, varscan2
- DEDD2 | c.448G>C p.G150R | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as COSV100260266, COSV60140854; called by muse, mutect2, varscan2
- DGKH | c.1187G>T p.W396L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54926992; called by muse, mutect2, varscan2
- DGKK | c.2941C>T p.R981C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101053125, COSV65706117; called by muse, varscan2
- DHX29 | c.1122G>T p.W374C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99287276; called by muse, mutect2, varscan2
- DHX29 | c.1121G>T p.W374L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99287283; called by muse, mutect2, varscan2
- DISP3 | c.1886C>A p.T629N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs774367781, COSV53819318; called by muse, mutect2, varscan2
- DMD | c.4694A>T p.Q1565L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV63732409, COSV63750140; called by muse, mutect2, varscan2
- DMWD | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV52174880; called by muse, mutect2, varscan2
- DNAH11 | c.8544G>C p.Q2848H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV60937086; called by muse, mutect2
- DOCK2 | c.3728C>A p.T1243K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56939153, COSV56983711; called by muse, mutect2, varscan2
- DRP2 | c.1628G>T p.R543L | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65809074, COSV65809315; called by muse, mutect2, varscan2
- DSC2 | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV51860693; called by muse, mutect2, varscan2
- DUSP7 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.166); catalogued as COSV56588516; called by muse, mutect2, varscan2
- EED | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54552831; called by muse, mutect2, varscan2
- ELMO2 | c.991A>G p.S331G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV51680905; called by muse, mutect2, varscan2
- EMP3 | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.283); catalogued as COSV99536674; called by muse, mutect2, varscan2
- EPHA3 | c.970+1G>A p.X324_splice | Splice Site (SNP) | VAF 23/117 reads (20%) | catalogued as rs754818412, COSV60692385, COSV60716695; called by muse, mutect2, varscan2
- EPHA5 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 24/99 reads (24%) | catalogued as COSV56628082; called by muse, mutect2, varscan2
- ESPNL | c.2755T>A p.F919I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV58031785; called by muse, mutect2, varscan2
- ESRRB | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55058005; called by muse, mutect2, varscan2
- EYA1 | c.685T>A p.Y229N | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58156360; called by muse, mutect2, varscan2
- EYS | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60996738; called by muse, varscan2
- EYS | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV100676428, COSV60991641; called by muse, varscan2
- FAM13C | c.268A>G p.R90G | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV53242296; called by muse, mutect2, varscan2
- FAM47B | c.222C>A p.D74E | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.773); catalogued as COSV100264307, COSV61452257; called by muse, varscan2
- FAM47B | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV61452280; called by muse, varscan2
- FAM71B | c.1212C>G p.S404R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.591); catalogued as COSV57227308; called by mutect2, varscan2
- FAM83B | c.1528G>C p.D510H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV60918820, COSV60926963; called by muse, mutect2, varscan2
- FBN2 | c.5843G>C p.C1948S | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV52489789; called by muse, mutect2, varscan2
- FGD1 | c.921C>A p.S307R | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV64307962; called by muse, mutect2, varscan2
- FLG | c.1979C>G p.P660R | Missense Mutation (SNP) | VAF 83/442 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs775331217, COSV64235619, COSV64244444; called by muse, mutect2, varscan2
- FOSL2 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs143327177, COSV53103257, COSV99268362; called by muse, mutect2, varscan2
- FSTL5 | c.1703C>A p.S568* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV60178930, COSV60186532; called by muse, mutect2, varscan2
- GJA10 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV65354693; called by muse, mutect2, varscan2
- GLI3 | c.3152G>T p.R1051L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as COSV67884634, COSV67888876; called by muse, mutect2, varscan2
- GNG13 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV99242834; called by muse, mutect2, varscan2
- GNG13 | c.45C>A p.S15R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs956248473, COSV99242835; called by muse, mutect2, varscan2
- GPIHBP1 | c.293C>A p.T98N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV58208983; called by muse, mutect2, varscan2
- GPRASP1 | c.2896G>T p.G966W | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV64354679; called by muse, varscan2
- GPRASP1 | c.2972C>G p.S991C | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV64354684; called by muse, varscan2
- GRID2 | c.529+1G>A p.X177_splice | Splice Site (SNP) | VAF 18/77 reads (23%) | catalogued as COSV56167761; called by muse, mutect2, varscan2
- GRIN2A | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58018195; called by muse, mutect2, varscan2
- GRM8 | c.1955G>T p.R652L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58797967, COSV58825269; called by muse, mutect2, varscan2
- GTF3C1 | c.5954G>T p.R1985L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62238548, COSV62244037; called by muse, mutect2, varscan2
- HNRNPCL1 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58609554; called by muse, mutect2, varscan2
- HRH3 | c.1070C>A p.A357D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58047380; called by muse, mutect2, varscan2
- HSD17B10 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV51447366; called by muse, mutect2, varscan2
- HUWE1 | c.8646G>C p.Q2882H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.191); catalogued as COSV53332939; called by muse, mutect2, varscan2
- IKBKE | c.1150A>G p.T384A | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs782501971, COSV65624153; called by muse, mutect2, varscan2
- IKZF3 | c.1050G>C p.E350D | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV53099250; called by muse, mutect2, varscan2
- INO80D | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68957931, COSV68959531; called by muse, mutect2, varscan2
- INTS14 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.149); catalogued as COSV57525344; called by muse, mutect2, varscan2
- IQSEC1 | c.2619G>T p.E873D | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV56220753; called by muse, mutect2, varscan2
- ITPRID2 | c.866G>C p.S289T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); catalogued as COSV57469142; called by muse, mutect2, varscan2
- JSRP1 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as COSV55553313; called by muse, mutect2, varscan2
- KCNB1 | c.2408C>A p.P803H | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV65565720; called by muse, mutect2, varscan2
- KCNE1 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs769368494, CM150045, COSV61606175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ3 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV54530597; called by muse, mutect2, varscan2
- KCNJ3 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1040094913, COSV54530610; called by muse, mutect2, varscan2
- KCNK2 | c.235G>A p.V79M (on ENST00000444842 / NM_001017425.3; = p.V64M on NM_014217.4) | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV67202883, COSV67208008; called by muse, mutect2
- KCNK2 | c.745G>T p.E249* (on ENST00000444842 / NM_001017425.3; = p.E234* on NM_014217.4) | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | catalogued as COSV67202886; called by muse, mutect2, varscan2
- KCNQ3 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV66463039, COSV66469744; called by muse, mutect2, varscan2
- KIR3DL1 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100428614; called by muse, mutect2, varscan2
- KMT2D | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs1253638323, COSV56407319, COSV56493934; called by muse, mutect2, varscan2
- LAMA3 | c.8303G>T p.R2768L (on ENST00000313654 / NM_198129.4; = p.R1159L on NM_000227.6) | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52528973; called by muse, mutect2, varscan2
- LAMB3 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1347157076, COSV61914990; called by muse, mutect2
- LAMC1 | c.918T>A p.N306K | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0.155); catalogued as COSV51132043; called by muse, mutect2, varscan2
- LCE2D | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.01); catalogued as COSV64228811; called by muse, mutect2, varscan2
- LHCGR | c.1517G>T p.S506I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54291879; called by muse, mutect2, varscan2
- LILRA2 | c.1247T>A p.V416E | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV52187620; called by muse, mutect2, varscan2
- LINGO2 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58056378; called by muse, mutect2, varscan2
- LRP1B | c.2980G>T p.G994W | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67182003; called by muse, mutect2, varscan2
- LRP2 | c.7543G>T p.D2515Y | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55538893, COSV55549705; called by muse, mutect2, varscan2
- LTBP1 | c.1492C>A p.H498N (on ENST00000404816 / NM_206943.4; = p.H172N on NM_000627.4) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV63178643; called by muse, mutect2, varscan2
- LUM | c.337T>A p.S113T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.292); catalogued as COSV57127353; called by muse, mutect2, varscan2
- LY75 | c.3785A>G p.K1262R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs1432604457, COSV55101364; called by muse, mutect2, varscan2
- MAGEB18 | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV57463278; called by muse, mutect2, varscan2
- MAGEB3 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.147); catalogued as COSV64396682; called by muse, mutect2, varscan2
- MAP3K21 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64043171; called by muse, mutect2
- MC3R | c.103T>A p.C35S | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV54762860; called by muse, mutect2, varscan2
- MCM4 | c.1342T>G p.L448V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV50621067; called by muse, mutect2, varscan2
- MDN1 | c.15329T>A p.M5110K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV65516330; called by muse, mutect2, varscan2
- MED13L | c.434G>T p.W145L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56115084; called by muse, mutect2, varscan2
- MEIS2 | c.1117G>T p.G373C (on ENST00000561208 / NM_170675.5; = p.G353C on NM_002399.3) | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54930641; called by muse, mutect2, varscan2
- MIB1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as rs1317522131, COSV55087426; called by muse, mutect2, varscan2
- MKRN2 | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as COSV50103606; called by muse, varscan2
- MMP17 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62178183, COSV62178195; called by muse, mutect2, varscan2
- MOB3B | c.454A>T p.K152* | Nonsense Mutation (SNP) | VAF 55/198 reads (28%) | catalogued as COSV51774343; called by muse, mutect2, varscan2
- MORC1 | c.342T>G p.F114L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV51712869, COSV51716176; called by muse, mutect2, varscan2
- MS4A14 | c.1651C>A p.Q551K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV55732732; called by muse, mutect2, varscan2
- MSRB2 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as rs373939180, COSV64737042; called by muse, mutect2, varscan2
- MTM1 | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.019); catalogued as COSV60333493; called by muse, mutect2, varscan2
- MTM1 | c.606G>C p.L202F | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); catalogued as COSV60333502; called by muse, mutect2, varscan2
- MYH11 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100258913; called by muse, mutect2, varscan2
- MYH11 | c.1710G>T p.K570N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100257863, COSV100258916; called by muse, mutect2, varscan2
- NIN | c.2040G>C p.Q680H | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55379130; called by muse, mutect2, varscan2
- NPR3 | c.995T>C p.F332S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54083838; called by muse, mutect2, varscan2
- NTNG1 | c.151del p.Q51Sfs*7 | Frame Shift Del (DEL) | VAF 23/103 reads (22%) | catalogued as COSV53984822; called by mutect2, pindel, varscan2
- NUP133 | c.523G>T p.V175F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV54567748; called by muse, mutect2, varscan2
- NUTM2F | c.1049G>T p.R350M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1386539662, COSV53555062; called by muse, mutect2, varscan2
- NWD1 | c.2221C>A p.R741S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV60336819; called by muse, mutect2, varscan2
- OCRL | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs769140259, COSV63979996; called by muse, mutect2
- OR10W1 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV67720146; called by muse, mutect2, varscan2
- OR13F1 | c.592A>T p.I198F | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV58250597; called by muse, mutect2, varscan2
- OR2G3 | c.138C>G p.I46M | Missense Mutation (SNP) | VAF 107/235 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV60680644, COSV60682304; called by muse, mutect2, varscan2
- OR2L13 | c.132G>C p.M44I | Missense Mutation (SNP) | VAF 92/195 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63547413; called by muse, mutect2, varscan2
- OR2M4 | c.27C>A p.N9K | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV60707075; called by muse, mutect2, varscan2
- OR51G2 | c.911T>A p.I304N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV58991674; called by muse, mutect2, varscan2
- OR51S1 | c.349G>A p.V117I | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV59057081; called by muse, mutect2, varscan2
- OR52A1 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.019); catalogued as COSV61091891; called by muse, mutect2, varscan2
- OR5D18 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV61736021; called by muse, mutect2, varscan2
- OR5H15 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as rs1291822286, COSV100736663; called by muse, mutect2, varscan2
- OR5T2 | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV57587630; called by muse, mutect2, varscan2
- OR6Y1 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as rs372365884, COSV56928014, COSV56930171; called by muse, mutect2, varscan2
- OR9K2 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.076); catalogued as rs772074536, COSV59531241; called by muse, mutect2, varscan2
- OSBPL1A | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60194717; called by muse, mutect2, varscan2
- PADI1 | c.997A>G p.N333D | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV64937701; called by muse, mutect2, varscan2
- PAGE2 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100892301; called by muse, mutect2, varscan2
- PAPPA2 | c.2044C>T p.H682Y | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV62772043; called by muse, mutect2
- PAPPA2 | c.3934G>T p.G1312* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV62789759; called by muse, mutect2, varscan2
- PAQR9 | c.1112C>A p.S371Y | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV61417445; called by muse, mutect2, varscan2
- PARD3B | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62501422; called by muse, mutect2, varscan2
- PCDH10 | c.1115C>A p.A372E | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.911); catalogued as rs1199200354, COSV52086654, COSV52088666; called by muse, mutect2, varscan2
- PCDH15 | c.4958C>A p.T1653K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0.02); catalogued as COSV64670190; called by muse, varscan2
- PCDHA1 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV65372406; called by muse, varscan2
- PCDHA1 | c.521C>A p.P174Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.47); catalogued as COSV65372412; called by muse, varscan2
- PCDHB14 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs370415569; called by muse, mutect2, varscan2
- PCDHB3 | c.1610G>T p.G537V | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50563875; called by muse, mutect2, varscan2
- PCDHB6 | c.1339C>A p.P447T | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50689492; called by muse, mutect2, varscan2
- PDZRN3 | c.2860C>G p.R954G | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55189976, COSV55196553, COSV55212179; called by muse, mutect2, varscan2
- PEBP1 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV54336640; called by muse, mutect2
- PELI2 | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV50709810; called by muse, mutect2
- PENK | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 83/164 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100152100, COSV59239901; called by muse, mutect2, varscan2
- PEPD | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54886666; called by muse, mutect2, varscan2
- PFKP | c.264+1G>T p.X88_splice | Splice Site (SNP) | VAF 33/142 reads (23%) | catalogued as rs1422778134, COSV66894531; called by muse, mutect2, varscan2
- PLP1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.403); catalogued as COSV58275371; called by muse, varscan2
- PLP1 | c.415T>A p.C139S | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV58275382; called by muse, varscan2
- PNCK | c.391G>T p.G131W (on ENST00000340888 / NM_001366975.1; = p.G214W on NM_001039582.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782815240, COSV61742385; called by muse, mutect2, varscan2
- POLN | c.505A>G p.S169G | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV67023105; called by muse, mutect2, varscan2
- POMT2 | c.430A>T p.M144L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55069400; called by muse, mutect2, varscan2
- POTEE | c.901C>A p.L301M | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV58223117; called by muse, mutect2, varscan2
- PPFIA2 | c.2099C>A p.P700Q | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV61018619; called by muse, mutect2, varscan2
- PPIL2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58604489; called by muse, mutect2, varscan2
- PPP1R26 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.542); catalogued as COSV63354543; called by muse, mutect2, varscan2
- PPRC1 | c.4264C>T p.R1422C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as rs368680880; called by muse, mutect2, varscan2
- PRDM9 | c.1248C>A p.F416L | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV57001762, COSV57002486; called by muse, mutect2, varscan2
- PREB | c.1030A>G p.I344V | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV53204314; called by muse, mutect2, varscan2
- PRKD1 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59558168; called by muse, mutect2, varscan2
- PRODH2 | c.409G>T p.A137S (on ENST00000301175; = p.A61S on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs770675022, COSV99995312; called by muse, mutect2, varscan2
- PROS1 | c.1901C>A p.A634D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV67774010; called by muse, mutect2, varscan2
- RAB3IL1 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV100076604; called by muse, mutect2
- RAB40C | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV50192772; called by muse, mutect2
- RFFL | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV52070577; called by muse, mutect2, varscan2
- RNASE12 | c.422G>C p.S141T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV60087219; called by muse, mutect2, varscan2
- RNF128 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.878); catalogued as COSV55248550; called by muse, mutect2
- RNF25 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 138/399 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55305672, COSV55307609; called by muse, mutect2, varscan2
- ROR2 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV65216043, COSV65223047; called by muse, mutect2, varscan2
- RPS3 | c.620A>G p.H207R | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53704037; called by muse, mutect2, varscan2
- RSPO4 | c.381G>T p.L127F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.387); catalogued as COSV54080109; called by muse, mutect2, varscan2
- S100B | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV52452570; called by muse, mutect2
- SBNO1 | c.4153C>T p.Q1385* (on ENST00000420886; = p.Q1384* on NM_018183.5) | Nonsense Mutation (SNP) | VAF 35/314 reads (11%) | catalogued as COSV57338435; called by muse, mutect2, varscan2
- SCMH1 | c.1074A>T p.T358= (on ENST00000326197 / NM_001031694.2; = p.T311= on NM_012236.4) | Splice Region (SNP) | VAF 29/105 reads (28%) | catalogued as COSV58231840; called by muse, mutect2, varscan2
- SCTR | c.885G>T p.W295C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50026687; called by muse, mutect2, varscan2
- SCTR | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as COSV50026690; called by muse, mutect2, varscan2
- SEMA5A | c.2824T>C p.F942L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV66783423; called by muse, mutect2, varscan2
- SH3TC2 | c.3470C>G p.T1157R | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV60460428; called by muse, mutect2, varscan2
- SHISAL1 | c.224A>T p.E75V | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66987367; called by muse, mutect2, varscan2
- SI | c.1079G>T p.W360L | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV52264324; called by muse, mutect2, varscan2
- SLC14A2 | c.2078G>T p.W693L | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV54905699, COSV99675131; called by muse, mutect2, varscan2
- SLC6A8 | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV53471395; called by muse, mutect2, varscan2
- SON | c.5644G>T p.G1882* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99278254; called by muse, mutect2, varscan2
- SPAG4 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs752863592, COSV65329886; called by muse, mutect2, varscan2
- SPHK2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as COSV55334317; called by muse, mutect2, varscan2
- SSBP3 | c.662G>C p.S221T (on ENST00000371320 / NM_145716.4; = p.S201T on NM_018070.5) | Missense Mutation (SNP) | VAF 118/365 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV58884049; called by muse, mutect2, varscan2
- STAG1 | c.2261A>G p.D754G | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52600215; called by muse, mutect2, varscan2
- STARD8 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); catalogued as COSV99366835; called by muse, mutect2, varscan2
- STOX1 | c.2696A>T p.Q899L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV53812575; called by muse, mutect2, varscan2
- SYNE2 | c.18268C>G p.L6090V | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59938259; called by muse, mutect2, varscan2
- SYT5 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62829586; called by muse, mutect2, varscan2
- TADA1 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63309791; called by muse, mutect2
- TAFA2 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV69171343, COSV69176822; called by muse, mutect2, varscan2
- TAOK3 | c.1747T>C p.S583P | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as COSV66824555; called by muse, mutect2, varscan2
- TBX5 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV59858174; called by muse, mutect2, varscan2
- TDRD6 | c.1684G>T p.D562Y | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV60173650; called by muse, mutect2, varscan2
- TECPR1 | c.135C>G p.C45W | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65782456; called by muse, mutect2
- TEX11 | c.1158G>T p.K386N (on ENST00000344304; = p.K371N on NM_031276.3) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.702); catalogued as COSV60225549; called by muse, mutect2, varscan2
- TEX11 | c.449C>A p.A150D (on ENST00000344304; = p.A135D on NM_031276.3) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.109); catalogued as COSV100721707; called by muse, mutect2, varscan2
- TIAM2 | c.586C>A p.Q196K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.127); catalogued as COSV59688444; called by muse, mutect2, varscan2
- TMC7 | c.1518C>G p.I506M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV58581241; called by muse, mutect2, varscan2
- TMEM145 | c.1129G>C p.A377P | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as COSV56623610, COSV56626359; called by muse, mutect2, varscan2
- TMEM187 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.316); catalogued as COSV64141062; called by muse, mutect2, varscan2
- TMPRSS11D | c.536T>A p.L179Q | Missense Mutation (SNP) | VAF 81/228 reads (36%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.98); catalogued as COSV52221321; called by muse, mutect2, varscan2
- TNR | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV54867737, COSV54881726; called by muse, mutect2, varscan2
- TNS3 | c.2582G>T p.R861L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60786219, COSV60790280; called by muse, mutect2, varscan2
- TOPORS | c.3122A>G p.D1041G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV62115960; called by muse, mutect2, varscan2
- TRIM27 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as rs1456038419, COSV65873174; called by muse, mutect2, varscan2
- TRPV5 | c.1345G>T p.G449W | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54682752; called by muse, mutect2, varscan2
- TSNARE1 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV56170118; called by muse, mutect2, varscan2
- TTBK1 | c.477C>G p.N159K | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52487779; called by muse, mutect2, varscan2
- TTC7B | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100127918; called by muse, mutect2, varscan2
- TTC7B | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100127920; called by muse, mutect2, varscan2
- TTLL11 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as COSV58641560; called by muse, mutect2, varscan2
- TWNK | c.1821G>C p.K607N | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61325457; called by muse, mutect2
- UAP1L1 | c.579C>A p.N193K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV64306084; called by muse, mutect2, varscan2
- UBQLN2 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV57738921; called by muse, mutect2, varscan2
- UPF3B | c.897A>T p.E299D (on ENST00000276201 / NM_080632.3; = p.E286D on NM_023010.3) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV52229108; called by muse, mutect2, varscan2
- USP34 | c.9058G>T p.A3020S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.956); catalogued as COSV68397416; called by muse, mutect2, varscan2
- USP6NL | c.2446A>C p.N816H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV53208674; called by muse, mutect2, varscan2
- UTP6 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV55571178; called by muse, mutect2, varscan2
- VANGL1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV59619127, COSV59622424; called by muse, mutect2, varscan2
- VASH1 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.407); catalogued as COSV51335089; called by muse, mutect2
- VMA21 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57755765; called by muse, mutect2, varscan2
- VWA8 | c.2851A>G p.I951V | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV55691381; called by muse, mutect2, varscan2
- VWC2L | c.547A>G p.I183V | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV56964747; called by muse, mutect2, varscan2
- WDR49 | c.94A>T p.N32Y (on ENST00000308378 / NM_001366158.1; = p.N373Y on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57701318; called by muse, mutect2, varscan2
- WIPF1 | c.601C>G p.R201G | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV55810856, COSV55812755; called by muse, mutect2, varscan2
- YWHAZ | c.678+1G>T p.X226_splice | Splice Site (SNP) | VAF 51/113 reads (45%) | catalogued as COSV62053268; called by muse, mutect2, varscan2
- ZC3H12C | c.1689G>A p.M563I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53706133; called by muse, mutect2, varscan2
- ZFR2 | c.1426A>G p.S476G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs777627266, COSV53595973; called by muse, mutect2, varscan2
- ZIC1 | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51552148; called by muse, mutect2, varscan2
- ZIC3 | c.508G>C p.A170P | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV54971966; called by muse, mutect2, varscan2
- ZKSCAN7 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV56271476, COSV56274668; called by muse, mutect2, varscan2
- ZMYM3 | c.3006G>C p.K1002N | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV100077956, COSV58735755; called by muse, mutect2, varscan2
- ZNF18 | c.1243A>T p.K415* | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as COSV59550476; called by muse, mutect2, varscan2
- ZNF233 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.638); catalogued as COSV61933142; called by muse, mutect2, varscan2
- ZNF33B | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV63941736; called by muse, mutect2, varscan2
- ZNF407 | c.5449G>A p.E1817K | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100225746; called by muse, mutect2
- ZNF445 | c.2430G>T p.R810S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV68538344; called by muse, mutect2, varscan2
- ZNF479 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); catalogued as COSV100482739; called by muse, mutect2, varscan2
- ZNF484 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV60255939; called by muse, mutect2, varscan2
- ZNF536 | c.1331C>A p.A444D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.074); catalogued as COSV62817480, COSV62824151; called by muse, mutect2, varscan2
- ZNF595 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs782261022, COSV59546710, COSV59554555; called by muse, mutect2, varscan2
- ZNF630 | c.1962G>C p.L654F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.378); catalogued as COSV52094806; called by muse, mutect2, varscan2
- ZNF680 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59013636; called by muse, mutect2
- ZNF875 | c.1423G>T p.G475W | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183316; called by muse, mutect2, varscan2
- ZNF875 | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100183319; called by muse, mutect2, varscan2
- ZPLD1 | c.806G>C p.S269T (on ENST00000466937 / NM_001329788.1; = p.S285T on NM_175056.2) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV60351523; called by muse, mutect2, varscan2
- ZRSR2 | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV57063193; called by muse, mutect2, varscan2
- ALG11 | c.569dup p.C191Lfs*28 | Frame Shift Ins (INS) | VAF 26/94 reads (28%) | called by mutect2, pindel, varscan2
- CNKSR2 | c.857del p.P286Rfs*6 | Frame Shift Del (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.2572A>T p.N858Y | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEATR9 | c.491A>C p.E164A | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- HSFX1 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- IGLV3-32 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- IGSF3 | c.3480del p.K1161Rfs*33 (on ENST00000369486 / NM_001007237.3; = p.K1181Rfs*33 on NM_001542.4) | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- LAMA5 | c.8509del p.L2837Sfs*14 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by pindel, varscan2
- LCE2A | c.39del p.K15Sfs*55 | Frame Shift Del (DEL) | VAF 53/270 reads (20%) | called by mutect2, pindel, varscan2
- MRC1 | c.3245G>T p.R1082L | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMCR8 | c.485del p.Q162Rfs*22 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- SRSF10 | c.504_514delinsC p.N169Ffs*20 | Frame Shift Del (DEL) | VAF 30/108 reads (28%) | called by pindel, varscan2*
- ST3GAL4 | c.352del p.R118Afs*30 (on ENST00000392669 / NM_001254758.1; = p.R114Afs*30 on NM_006278.3) | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- UNC79 | c.3788dup p.D1264Gfs*29 (on ENST00000393151 / NM_001346218.2; = p.D1087Gfs*29 on NM_020818.5) | Frame Shift Ins (INS) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- ACKR1 | c.846G>T p.L282= | Silent (SNP) | VAF 133/280 reads (48%) | catalogued as COSV63671579; called by muse, mutect2, varscan2
- ACSM2A | c.1518G>A p.K506= (on ENST00000219054; = p.K427= on NM_001308169.2) | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as COSV54581704; called by muse, mutect2, varscan2
- ACTN2 | c.574C>A p.R192= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as COSV63971413, COSV63977125; called by muse, mutect2, varscan2
- ADAMTS2 | c.640C>A p.R214= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV51071622; called by muse, mutect2, varscan2
- AFAP1L1 | c.1014G>A p.L338= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as COSV57043638; called by muse, mutect2
- AGT | c.390G>T p.G130= | Silent (SNP) | VAF 34/154 reads (22%) | catalogued as COSV64183613; called by muse, mutect2, varscan2
- AHR | c.216C>T p.L72= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV54121254; called by muse, mutect2, varscan2
- ALAS2 | c.1011C>A p.I337= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV58187864; called by muse, mutect2, varscan2
- ARSH | c.423C>T p.Y141= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs761467371, COSV66962459; called by muse, mutect2, varscan2
- ART1 | c.516C>A p.P172= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV51702691; called by muse, mutect2, varscan2
- ASXL3 | c.3600G>C p.V1200= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV52455891; called by muse, mutect2, varscan2
- BIRC2 | c.744A>G p.P248= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs1473587028, COSV57160498; called by muse, mutect2, varscan2
- BNC1 | c.2490G>T p.L830= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV61756365; called by muse, mutect2, varscan2
- BTN3A1 | c.645G>T p.G215= | Silent (SNP) | VAF 53/228 reads (23%) | catalogued as COSV50024405; called by muse, mutect2, varscan2
- C2orf80 | c.24G>A p.K8= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV58015149; called by muse, mutect2, varscan2
- CABS1 | c.720C>A p.T240= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs754538156, COSV56732863; called by muse, mutect2, varscan2
- CCDC74A | c.1047A>G p.A349= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs189219021; called by muse, mutect2, varscan2
- CCER1 | c.90C>G p.A30= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV62645750; called by muse, mutect2
- CDH10 | c.1839C>A p.A613= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as rs141786276, COSV52568220; called by muse, mutect2, varscan2
- CFC1 | c.195C>T p.A65= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs767782271, COSV52090220; called by muse, mutect2, varscan2
- CPXM1 | c.1992G>C p.L664= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV66044502; called by muse, mutect2, varscan2
- CRB1 | c.1974C>A p.I658= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV66328480; called by muse, mutect2, varscan2
- CSMD1 | c.8691G>C p.T2897= (on ENST00000520002; = p.T2896= on NM_033225.6) | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV59276636, COSV59330022; called by muse, mutect2, varscan2
- CYP4F2 | c.1236G>T p.R412= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV55616047; called by muse, mutect2, varscan2
- DDR1 | c.2463G>T p.T821= (on ENST00000324771; = p.T784= on NM_001954.4) | Silent (SNP) | VAF 90/232 reads (39%) | catalogued as COSV61318493; called by muse, mutect2, varscan2
- DDX60L | c.2421T>A p.T807= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV52708226; called by muse, mutect2
- DENND4C | c.1539C>T p.C513= | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV66821354, COSV66821991; called by muse, mutect2, varscan2
- DHX34 | c.1698C>A p.A566= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV60894253; called by muse, mutect2, varscan2
- EBF1 | c.345C>G p.L115= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV58165924; called by muse, mutect2
- EMP3 | c.18G>T p.L6= | Silent (SNP) | VAF 60/250 reads (24%) | catalogued as COSV99536669; called by muse, mutect2, varscan2
- FAM135B | c.3327A>G p.E1109= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV52702008; called by muse, mutect2, varscan2
- FASLG | c.243G>T p.L81= | Silent (SNP) | VAF 24/42 reads (57%) | catalogued as rs760651511, COSV60679608; called by muse, mutect2, varscan2
- FBXL7 | c.312C>A p.A104= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV61640480; called by muse, mutect2, varscan2
- GAK | c.588G>T p.T196= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100033814, COSV58502468; called by muse, mutect2, varscan2
- GP2 | c.1449C>G p.R483= (on ENST00000381362 / NM_001007240.3; = p.R480= on NM_001502.4) | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV56891847; called by muse, mutect2, varscan2
- GPNMB | c.742C>A p.R248= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV51696592; called by muse, mutect2, varscan2
- HCN1 | c.1140C>T p.I380= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs756675765, COSV57490916; called by muse, mutect2, varscan2
- HMCN1 | c.285A>T p.T95= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV54873057; called by muse, mutect2, varscan2
- HYDIN | c.2184C>T p.L728= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV55475359; called by muse, mutect2, varscan2
- IGSF22 | c.702C>A p.I234= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV60030384; called by muse, mutect2, varscan2
- KCTD15 | c.681C>G p.L227= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV52288689; called by muse, mutect2, varscan2
- KPNA3 | c.1380G>A p.E460= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55502937; called by muse, mutect2, varscan2
- KRIT1 | c.2007C>T p.L669= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV60666598; called by muse, mutect2, varscan2
- LAMA1 | c.5982C>A p.L1994= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV67531066, COSV67532572; called by muse, mutect2, varscan2
- LILRA4 | c.1237C>T p.L413= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs751625685, COSV52489975; called by muse, varscan2
- LILRB5 | c.1089C>G p.P363= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV100300246, COSV100300786, COSV60254150; called by muse, mutect2, varscan2
- LRRC7 | c.4029A>T p.S1343= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV50408810; called by muse, mutect2, varscan2
- MAGEB3 | c.55C>A p.R19= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV64396679; called by muse, mutect2, varscan2
- MAP1LC3C | c.354C>A p.T118= | Silent (SNP) | VAF 18/124 reads (15%) | catalogued as COSV61803453, COSV61803842; called by muse, mutect2, varscan2
- MID1 | c.1662C>A p.A554= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV58191188; called by muse, mutect2, varscan2
- MKI67 | c.8646G>A p.T2882= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as rs372328060; called by muse, mutect2
- MLST8 | c.99C>T p.I33= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs374945803; called by muse, mutect2, varscan2
- MUC17 | c.9033T>C p.P3011= | Silent (SNP) | VAF 171/522 reads (33%) | catalogued as COSV60278998; called by muse, mutect2, varscan2
- MVD | c.396C>T p.A132= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV56329525; called by muse, mutect2, varscan2
- MYBPC2 | c.690C>G p.A230= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV63092943; called by muse, mutect2, varscan2
- MYH15 | c.1944G>A p.K648= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV56303638; called by muse, mutect2
- NCAM1 | c.759G>A p.Q253= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV57509537; called by muse, mutect2
- NEK10 | c.963C>T p.D321= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV58278813; called by muse, mutect2, varscan2
- NHS | c.4269A>G p.L1423= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV66270838; called by muse, mutect2, varscan2
- NLRP12 | c.2175G>T p.L725= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV60743106; called by muse, mutect2, varscan2
- OCIAD2 | c.168G>A p.L56= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV56716079; called by muse, mutect2, varscan2
- OR2F2 | c.234C>A p.V78= | Silent (SNP) | VAF 75/267 reads (28%) | catalogued as rs760268945, COSV68832460; called by muse, mutect2, varscan2
- OR2T8 | c.780C>A p.P260= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV60661122; called by muse, mutect2, varscan2
- PAPPA | c.4179G>A p.R1393= | Silent (SNP) | VAF 25/90 reads (28%) | catalogued as COSV60276656; called by muse, mutect2, varscan2
- PCDHA11 | c.1404A>C p.P468= | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as COSV56474534; called by muse, mutect2, varscan2
- PJA1 | c.393T>A p.A131= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV64052504; called by muse, mutect2, varscan2
- PPL | c.3060G>T p.L1020= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV52165339; called by muse, mutect2, varscan2
- RYR1 | c.2064C>A p.T688= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV62087193, COSV62097525; called by muse, mutect2, varscan2
- SEC31A | c.3222C>A p.G1074= (on ENST00000355196 / NM_001318120.1; = p.G1035= on NM_016211.4) | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as COSV52340883; called by muse, mutect2, varscan2
- SH2D5 | c.117G>C p.L39= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100903840; called by muse, mutect2, varscan2
- SLC19A1 | c.303C>A p.L101= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV60752802; called by muse, mutect2, varscan2
- SMG1 | c.7239G>T p.L2413= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV67169160, COSV67173613; called by muse, mutect2
- SNTG1 | c.180C>T p.I60= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV52422851; called by muse, mutect2, varscan2
- SPATA31A3 | c.537C>A p.S179= | Silent (SNP) | VAF 26/121 reads (21%) | called by mutect2, varscan2
- SYPL2 | c.801A>T p.G267= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV63993242; called by muse, mutect2, varscan2
- TAF1L | c.207G>A p.G69= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV54256270; called by muse, mutect2, varscan2
- TAF7L | c.24C>G p.L8= | Silent (SNP) | VAF 87/369 reads (24%) | catalogued as COSV63299193, COSV63300455; called by muse, mutect2, varscan2
- TFDP3 | c.909G>A p.G303= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV59535701; called by muse, mutect2, varscan2
- TKTL1 | c.243C>A p.V81= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV54211514; called by muse, mutect2, varscan2
- TMF1 | c.2634A>T p.V878= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV68373291; called by muse, mutect2, varscan2
- TNNT2 | c.306G>C p.R102= | Silent (SNP) | VAF 24/226 reads (11%) | catalogued as COSV52660575; called by muse, mutect2, varscan2
- TRIM29 | c.957G>T p.R319= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV59278821; called by muse, mutect2, varscan2
- TRIM58 | c.1056G>T p.V352= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs1287108098, COSV100825369, COSV63568911; called by muse, mutect2, varscan2
- TSC22D3 | c.69C>A p.S23= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as COSV59776913; called by muse, mutect2, varscan2
- TTPA | c.261A>G p.L87= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1324220704, COSV52645696; called by muse, mutect2, varscan2
- TUBB8 | c.466C>A p.R156= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV59114461; called by muse, mutect2, varscan2
- USP54 | c.1011C>T p.C337= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV60439308; called by muse, mutect2, varscan2
- XPNPEP2 | c.1761C>A p.T587= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV64368382; called by muse, mutect2, varscan2
- ZNF304 | c.531A>G p.P177= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV56583045; called by muse, mutect2, varscan2
- ZNF423 | c.2856G>T p.G952= (on ENST00000563137 / NM_001379286.1; = p.G944= on NM_015069.4) | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV52175174; called by muse, mutect2, varscan2
- ZNF875 | c.1647G>A p.G549= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV60989666; called by muse, mutect2, varscan2
- AC074085.2 | n.75C>A | RNA (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- AFDN | chr6:167826280 C>A | 5'Flank (SNP) | VAF 99/252 reads (39%) | catalogued as rs371605617; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83105C>T | Intron (SNP) | VAF 106/293 reads (36%) | catalogued as rs1180116518; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849455 C>A | 5'Flank (SNP) | VAF 9/46 reads (20%) | catalogued as rs1461678792; called by muse, mutect2, varscan2
- BEND6 | chr6:56954445 G>T | 5'Flank (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1451-2936C>G | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as rs919977708; called by muse, mutect2
- GPM6B | c.61+9086G>T | Intron (SNP) | VAF 46/121 reads (38%) | catalogued as COSV100366205; called by muse, mutect2
- GPM6B | c.61+9084G>C | Intron (SNP) | VAF 45/120 reads (38%) | catalogued as COSV100366207; called by muse, mutect2
- H2BP2 | n.1062-364G>T | Intron (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2, varscan2
- HMG20B | c.*308C>A | 3'UTR (SNP) | VAF 2/12 reads (17%) | catalogued as COSV99503044; called by muse, mutect2
- IGHV1-12 | n.193G>C | RNA (SNP) | VAF 16/41 reads (39%) | catalogued as rs782220149; called by muse, mutect2, varscan2
- LINC01600 | n.899C>A | RNA (SNP) | VAF 16/104 reads (15%) | called by muse, mutect2, varscan2
- LPAR4 | c.*1G>T | 3'UTR (SNP) | VAF 14/43 reads (33%) | catalogued as COSV101425112; called by muse, mutect2, varscan2
- NXF5 | n.1355A>T | RNA (SNP) | VAF 60/181 reads (33%) | catalogued as COSV53789450; called by muse, mutect2, varscan2
- SNORD114-15 | n.13G>C | RNA (SNP) | VAF 33/138 reads (24%) | called by muse, mutect2, varscan2
- TPM1 | c.563+288G>A | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99146932; called by muse, mutect2, varscan2
- ZNF99 | c.*768G>A | 3'UTR (SNP) | VAF 16/39 reads (41%) | catalogued as COSV68054541; called by muse, mutect2, varscan2
